HCMI case HCM-BROD-0488-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4ba45a91-c521-42cc-b2c5-8c4d04444d22

Demographics
Sex at birth: male; Race: white; Year of birth: 1945; Vital status: Alive.

Diagnoses (1)
1. Tubular adenocarcinoma: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: metastasis; Age at diagnosis: 65.5 years (23,912 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Fluorouracil + Irinotecan + Leucovorin + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 17 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant; Days to treatment start: 17 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab + Trastuzumab; Treatment intent type: Neoadjuvant; Days to treatment start: 2,507 days (6.9 years).
   Recorded as not given: adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 2,639 days (7.2 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 2,639 days (7.2 years).
- Days to follow up: 2,800 days (7.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- ERBB2 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 61 kg; BMI: 21.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (1 sample)
- Sample HCM-BROD-0488-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
